Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A3QX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A3QX-01A (Primary Tumor).

[page 1 of 5]
Surgical Pat
Case Number:

Diagnosis:

A: Peritoneum, right gutter, biopsy (FSA1)
- Metastatic serous carcinoma

B: Omentum, removal
- Metastatic serous carcinoma

C: Uterus and cervix, hysterectomy:

Location of tumor: anterior and posterior endometrium

Histologic type: serous adenocarcinoma (see comment)

Histologic grade (FIGO): grade 3

Extent of invasion:

Myometrial invasion: outer half
Depth: 2.4 cm Wall thickness: 2.5 cm
Percent: 95% (C7, C8)

Serosal involvement: not identified

Lower uterine segment involvement: present (C3)

Cervical involvement: not identified

Adnexal involvement (see below): present

Other sites: not identified

Cervical/vaginal margin and distance: negative, at least 3.1 cm
(cervix is received detached)

Lymphovascular space invasion: present, extensive (C4)

Regional lymph nodes: no lymph nodes submitted

Other pathologic findings: intramural leiomyoma

Tumor estrogen receptor and progesterone receptor
immunohistochemistry results: ER positive (2-3+, 75%) and PR
weakly positive (2+, 10%) (C5)

Illegible Discrepancy		
SP/AS Discrepancy		

ICD-O-3

Adenocarcinoma, serous, NOS
8441/3

Site: endometrium
C54.1

330-12 RP

[page 2 of 5]
AJCC Pathologic Stage: pT4a pNx pMx
FIGO (classification) Stage grouping: IVA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

Ovary, right, oophorectomy:

- Poorly differentiated serous adenocarcinoma, tumor size up to 4.3 cm

Ovary, left, oophorectomy:

- Focal metastatic serous adenocarcinoma

Fallopian tube, right, salpingectomy:

- Intraluminal serous adenocarcinoma present without mural involvement

Fallopian tube, left, salpingectomy:

- No specific pathologic abnormality

COMMENT:

A representative block of the endometrial tumor (C8) is submitted for immunohistochemical evaluation, given the presence of tumor in both the endometrium and ovaries. The tumor shows only scant scattered weak positive staining for WT1 and is positive for E-cadherin. The predominant tumor in the endometrium and the absence of strong positive staining for WT1 supports classification as a tumor of primary endometrial origin.

Intraoperative Consult Diagnosis:

A frozen section was requested.

FSA1: Peritoneum, right gutter, biopsy

- Positive for high grade serous adenocarcinoma

Clinical History:

year-old female with endometrial cancer; outside not reviewed here yet (case was positive for serous adenocarcinoma of the endometrium).

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "peritoneum, right gutter" and consists of a 4.5 x 2.1 x 0.2 cm red-tan soft tissue

[page 3 of 5]
fragment. Within the soft tissue is a 0.3 x 0.3 x 0.2 cm white-tan firm nodule that was frozen as FSA1, the remainder of the specimen is submitted in A2, ---

Container B is additionally labeled "omentum." It consists of a 9.7 x 4.9 x 3.8 cm segment of omentum that contains approximately 10 firm, smooth, white, ill-defined nodules ranging from 0.5 cm in greatest dimension up to 3.7 x 1.7 x 1.0 cm in greatest dimension. These nodules are represented in blocks B1 and B2.

Container C is additionally labeled "uterus, cervix, bilateral tubes and ovaries."

Adnexa: bilateral present

Weight: 170 grams and includes the detached cervix

Shape: pyriform

Dimensions:

height: 8.2 cm

anterior to posterior width: 6.0 cm

breadth at fundus: 7.0 cm

Serosa: intact, pink/tan, smooth and glistening with focal red/brown adhesions along the posterior lateral aspect

Cervix: received detached

ectocervix: purple/white, smooth with erythema surrounding a 0.5 cm in diameter cervical os

endocervix: smooth and erythematous

length of endocervical canal: 3.1 cm

Endomyometrium:

length of endometrial cavity: 6.3 cm

width of endometrial cavity at fundus: 4.9 cm

tumor findings:

dimensions: 6.8 x 6.4 x 1.5 cm with an additional aggregate of tumor within the accompanying container (6.5 x 3.7 x 3.5 cm)

appearance: tan/gray, fungating, soft and friable

location and extent: anterior and posterior cavities, 2.1 cm from the anterior and posterior lower uterine

segment/endocervical canal interface; the mass extends all the way through a 2.5 cm thick myometrium up to the serosa but not through it

myometrial invasion: to the serosa

thickness of myometrial wall at deepest gross invasion: 2.5 cm

other findings or comments: There are two homogeneous white whorled, well circumscribed intramural nodules (0.5 cm in greatest dimension and 0.8 cm in greatest dimension).

[page 4 of 5]
Adnexa:

Right ovary:

dimensions: 4.3 x 3.2 x 2.9 cm

external surface: smooth, pink/tan and bulging

cut surface: approximately 90% of the cut surface consists of a multiloculated cyst with a wall thickness ranging from 0.1 cm up to 0.4 cm; the cyst is partially filled with a yellow transparent gelatinous fluid; the inner wall is smooth and has a 1.7 x 1.7 x 0.7 cm soft, white friable excrescence; within the thicker aspect of the wall is a 1.3 x 0.7 x 0.5 cm ill-defined soft smooth gray/white nodule that bulges the capsule, but does not extend through it; the capsule overlying the nodule is inked green; the uninvolved parenchyma is red/brown, hemorrhagic with a corpus albicans

Right fallopian tube:

dimensions: 5.4 cm long x 0.5 cm diameter

other findings: the fallopian tube is unremarkable

Left ovary:

dimensions: 2.3 x 1.4 x 1.0 cm

external surface: tan/yellow, cerebriform

cut surface: two simple cysts (0.5 cm in greatest dimension, up to 0.8 cm in greatest dimension); each filled with a translucent yellow-tinged gelatinous material; within the smaller cysts and extending into the parenchyma is a 0.5 x 0.5 x 0.3 cm ill-defined smooth firm white papillary excrescence; this excrescence bulges the capsule but does

not extend through it; on the surface of the capsule is a 0.7 x 0.7 x 0.5 cm well circumscribed smooth rubbery gray/white nodule

Left fallopian tube:

dimensions: 4.8 cm long x 0.5 cm in diameter

other findings: fallopian tube is unremarkable

Lymph nodes: none

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations: no

Block Summary:

C1 - anterior cervix

C2 - posterior cervix

C3 - perpendicular of anterior lower uterine segment with mass

C4 - perpendicular of posterior lower uterine segment with mass

C5,C6 - full thickness anterior endometrium with mass with

[page 5 of 5]
largest intramural nodule, one piece, bisected (serosa inked blue)

C7,C8 - posterior endomyometrium with mass, full thickness, bisected (serosa inked black)

C9,C10 - soft inner wall excrescence

C11 - intramural nodule

C12 - hemorrhagic ovarian parenchyma with corpus albicans and right fallopian tube, proximal/middle/distal

C13 - left ovary with papillary excrescence

C14 - surface capsular, left ovarian nodule

C15 - left fallopian tube, proximal/middle/distal

Source: NCI Genomic Data Commons file d25899ea-df6d-454c-baf4-d45d3ed212d3 (TCGA-EY-A3QX.8AED036E-FB86-42D1-B840-FB4AD6E8D0EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).